Somatic mutation profile of tumor specimen TCGA-HT-A61B-01A (aliquot TCGA-HT-A61B-01A-11D-A29Q-08) from TCGA case TCGA-HT-A61B, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 22.8 years (8,335 days).
Specimen TCGA-HT-A61B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8c6b61c-36db-4a11-97d4-18041649c56c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A61B-10A (Blood Derived Normal), aliquot TCGA-HT-A61B-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34abd230-ccbf-4d31-8579-b2c08f7cf9e7

The open-access MAF lists 40 somatic variants for this specimen: 34 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 28, Silent 6, Nonsense Mutation 4, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 47/52 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CARMIL1 | c.1857A>G p.I619M | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100278954; called by muse, mutect2, varscan2
- CDH12 | c.1912C>T p.R638* | Nonsense Mutation (SNP) | VAF 38/49 reads (78%) | catalogued as COSV66385895; called by muse, mutect2, varscan2
- CFAP65 | c.5464T>A p.S1822T | Missense Mutation (SNP) | VAF 142/290 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.402); catalogued as COSV100446023; called by muse, mutect2, varscan2
- CUL4B | c.408G>C p.E136D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.931); catalogued as COSV100341280; called by muse, mutect2, varscan2
- CYB5RL | c.99C>A p.C33* | Nonsense Mutation (SNP) | VAF 53/119 reads (45%) | catalogued as COSV99839224; called by muse, mutect2, varscan2
- DNASE1L3 | c.363C>G p.D121E | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100568871; called by muse, mutect2, varscan2
- EAPP | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 17/78 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as rs755078772, COSV99164271; called by muse, mutect2, varscan2
- ELP2 | c.1507G>T p.G503* | Nonsense Mutation (SNP) | VAF 28/50 reads (56%) | catalogued as COSV100626794; called by muse, mutect2, varscan2
- FAM126B | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99628321; called by muse, varscan2
- FAT2 | c.1376A>G p.N459S | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1363914536, COSV99944313; called by muse, mutect2, varscan2
- FLRT1 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.736); catalogued as rs766685302, COSV55357208; called by muse, mutect2, varscan2
- GOLGA4 | c.6640G>T p.E2214* | Nonsense Mutation (SNP) | VAF 30/84 reads (36%) | catalogued as COSV100728700; called by muse, mutect2, varscan2
- IL12RB1 | c.704A>C p.N235T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs774673380, COSV100443235; called by muse, varscan2
- IPO9 | c.2615A>G p.N872S | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs141172151; called by muse, mutect2, varscan2
- ITPR1 | c.1139G>A p.S380N (on ENST00000354582; = p.S365N on NM_002222.7) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV100233480; called by muse, mutect2, varscan2
- KIR2DL3 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as rs575503782, COSV100668136; called by muse, mutect2, varscan2
- MEGF6 | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 75/148 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV99621504; called by muse, mutect2, varscan2
- MINDY4 | c.1724T>C p.I575T | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV99519397; called by muse, mutect2, varscan2
- MMAA | c.7A>G p.M3V | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs527340737, COSV99850083; called by muse, mutect2, varscan2
- MRPS27 | c.161C>G p.A54G | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99782539; called by muse, mutect2, varscan2
- OR2T12 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100528016, COSV58778872; called by muse, mutect2, varscan2
- OR51Q1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as rs376977023; called by muse, mutect2, varscan2
- PAX2 | c.604A>G p.K202E | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100695480; called by muse, mutect2, varscan2
- PCDHA1 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV65372709, COSV65375023; called by muse, mutect2
- ST3GAL1 | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 37/113 reads (33%) | PolyPhen benign (0); catalogued as COSV100172619; called by muse, mutect2, varscan2
- STK32A | c.85A>G p.I29V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100097792; called by muse, varscan2
- TMEM132B | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs550549644, COSV54751336; called by muse, mutect2, varscan2
- TMPRSS11F | c.518T>G p.I173S | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100678858; called by muse, mutect2, varscan2
- TTF1 | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs757246175, COSV100524888; called by mutect2, varscan2
- ZAN | c.4375G>T p.A1459S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV100770522; called by muse, mutect2, varscan2
- ZNF560 | c.1637G>A p.C546Y | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100039118; called by muse, mutect2, varscan2
- GSPT1 | c.381dup p.D128Rfs*11 (on ENST00000420576 / NM_001130007.2; = p.D266Rfs*11 on NM_002094.4) | Frame Shift Ins (INS) | VAF 30/134 reads (22%) | called by mutect2, pindel, varscan2
- CTDNEP1 | c.294A>G p.V98= | Silent (SNP) | VAF 163/335 reads (49%) | catalogued as rs747693333, COSV100021197; called by muse, mutect2, varscan2
- GBA2 | c.807A>G p.G269= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as rs752862084, COSV100803527; called by muse, mutect2, varscan2
- HNRNPF | c.1167C>T p.Y389= | Silent (SNP) | VAF 121/267 reads (45%) | catalogued as rs375590998, COSV100563101, COSV61561063; called by muse, mutect2, varscan2
- PRR30 | c.1041C>T p.A347= | Silent (SNP) | VAF 39/149 reads (26%) | catalogued as rs769196777, COSV99574528; called by muse, mutect2, varscan2
- SPG7 | c.1950C>T p.I650= (on ENST00000268704; = p.I657= on NM_003119.4) | Silent (SNP) | VAF 37/157 reads (24%) | catalogued as rs140356355; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STK38L | c.579C>T p.Y193= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs1251416667, COSV101198834; called by muse, mutect2, varscan2
